Surgical pathology report (de-identified scan), TCGA case TCGA-09-2050, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2050-01A (Primary Tumor).

[page 1 of 7]
First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

[illegible]

D: Sigmoid attachment

E: LT pelvic lymph node

F: IT Periaortic lymph nodes

G: RT pelvic lymph nodes

H: RT periaortic lymph nodes

H&E, FIRST X 1

1. *Journal of Management Studies*, 1990, 27, 1, 1-14.

Appendix incidental

1. *Journal of Management Studies*, 1996, 33, 1, 1-14.

Final Pathologic Diagnosis:

A. Right ovary and fallopian tube, salpingo-oophorectomy specimen.

1. Papillary serous carcinoma; see comment.

2. Tumor focally (microscopically) extends to the

3. Fallopian tube involved by serous carcinoma.

B. Left ovary and fallopian tube, salpingo-oophorectomy specimen

1. Papillary serous carcinoma; see comment.

2. Tumor grossly (macroscopically and microscopically)

Page 1 of 7

of the ovary.

3. Fallopian tube not involved by tumor.

C. Uterus, hysterectomy:

1. Cervix: No tumor identified.

7. Endometrium: Inactive endometrium.

3. Myometrium: No significant pathologic abnormality.

[page 2 of 7]
4. Serosa: Negative for tumor involvement.
- D. Sigmoid colon, "attachment," biopsy: Fibrofatty tissue with serous adenocarcinoma.
- E. Left pelvic lymph node, excision: No tumor identified in four lymph nodes (0/4).
- F. Periaortic lymph nodes, excision: No tumor identified in three lymph nodes (0/3).
- G. Right pelvic lymph nodes, excision: No tumor identified in seven lymph nodes (0/7).
- H. Right periaortic lymph nodes, excision: No tumor identified in six lymph nodes (0/6).
- I. Omentum, omentectomy: Fibrofatty tissue with no tumor identified.
- J. Appendix, appendectomy: Fibrous obliteration of lumen; no tumor identified.

Note: Ovarian Tumor Synoptic Comment

1. Type of tumor: Papillary serous carcinoma.
2. Grade of tumor: II.
3. Location of tumor: Bilateral.
4. Diameter of tumor: Right ovary = 12.0 cm; left ovary = 11.1 cm.
5. Appearance of surface of ovary: Right ovary: smooth and intact (grossly); Left ovary: tumor on surface (grossly).
6. Condition of capsule: Right ovary: Microscopic tumor on surface; Left ovary: ruptured.
7. Appearance of cut surface: Solid and cystic, mainly solid.
8. Color of solid areas: Tan-yellow.
9. Necrosis: Focal.
10. Lymphatic/vascular invasion: Not identified.
11. Sites of metastases in pelvis: None.
12. Pelvic lymph nodes: No tumor identified in eleven lymph nodes (0/11).
13. Sites of metastases in abdomen: Serosa of sigmoid colon.
14. Para-aortic lymph nodes: No tumor identified in nine lymph nodes (0/9).
15. Peritoneal cytology: Negative. Cytology accession [REDACTED]
16. Other significant findings: None.
17. FIGO stage: IIA.
18. TNM stage: pT2aN0MX.

Estrogen receptors: The ovarian tumor stains weakly and focally (nuclear staining) positive for estrogen receptors. Progesteron receptors: The ovarian tumor stains strongly positive (nuclei) in some areas with negative staining in adjacent areas.

Result of Her-2/neu test: This ovarian carcinoma is negative for Her-2/neu oncoprotein overexpression.

An immunohistochemical assay was performed on block B3 using the CB11 monoclonal antibody to Her-2/neu oncoprotein. The staining intensity of this carcinoma was 0 on a scale of 0-3 with cytoplasmic staining only (Her-2 test interpreted by [REDACTED])

Page 2 of 7

Carcinomas with staining intensity scores of 0 or 1 are considered *negative* for overexpression of Her-2/neu oncoprotein.

Those with a staining intensity score of 2 are considered *borderline*. We and others have observed that many carcinomas with staining intensity scores of 2 do not show gene amplification. All carcinomas with staining intensity scores of 2 are therefore submitted for FISH testing. The results of the FISH test are issued directly from the molecular cytogenetics laboratory.

Carcinomas with staining intensity scores of 3 are considered *positive* for overexpression of Her-2/neu oncoprotein. Tumors in this category show an excellent correlation between the results of immunohistochemical and FISH testing, and almost always show gene amplification.

[page 3 of 7]
Intraoperative Consult Diagnosis

FS1 (A) Right ovary, biopsy: Malignant ovarian epithelial neoplasm. (D [REDACTED])

Clinical History

The patient is a [REDACTED] with bilateral adnexal masses and increasing CA125. [REDACTED] undergoes hysterectomy and bilateral salpingo-oophorectomy, right tumor debulking, removal of sigmoid implant, pelvic and peri-aortic lymph node dissection, omentectomy and appendectomy.

Gross Description

The specimen is received fresh in ten parts, each labeled with the patient's name and medical record number.

Part A, labeled "right ovary," consists of an ovary and attached fallopian tube weighing 280 gm and measuring 12.0 x 9.5 x 3.4 cm. The serosal surface is smooth, pink-gray and intact. It is entirely inked black. The ovary is bisected to reveal a cystic interior, as well as a large, 6.3 cm, tan-yellow, multinodular exophytic mass adherent to the walls of the cyst. This solid area comprises approximately 70% of the specimen. A representative section from this area is submitted for frozen section 1, and subsequently submitted in cassette A1. Multiple representative sections of the exophytic mass, in relation to the inked surface of the ovary, are submitted in cassettes A2-A10. Representative sections of the fallopian tube are submitted in cassette A11.

Part B, labeled "left ovary," consists of an ovary with attached fallopian tube weighing 142 gm and measuring 11.1 x 9.5 x 3.1 cm. The fallopian tube measures 8.0 cm in length and 0.6 cm in average diameter. The pink-gray serosal surface is disrupted in two areas. One of these areas has a 3.8 x 3.5 x 2.5 cm tan-brown, fungating exophytic mass penetrating the serosal surface. Peripheral to this are tan-yellow, fibrofatty adhesions. The external surface of the ovary is inked black. The ovary is opened to reveal a cystic cavity with two major loculations. The wall of the cyst is largely composed of an exophytic, multinodular, fungating, tan-brown mass that is adherent to the cyst wall. Representative sections of the exophytic mass on the surface of the ovary are submitted in cassettes B1-B2, along with representative cross-sections of fallopian tube in B1. Multiple representative sections of the solid components of the cyst are submitted in cassettes B3-B11.

Part C, labeled "uterus," consists of a uterus weighing 47 gm and measuring 6.5 cm from cervix to fundus, 4.5 cm from cornu to cornu and 1.8 cm from anterior to posterior. The cervical os is fish-mouthed and measures 0.5 cm. The cervix is unremarkable, except for scattered, apparent areas of hemorrhage. The specimen is oriented by the peritoneal reflections. The anterior surface is inked blue and the posterior surface is inked black. The serosal surface of the uterus is smooth and tan-brown. The uterus is opened to reveal an unremarkable endometrial surface with no areas of tumor or lesions grossly identifiable. The endometrium measures 3.1 x 1.1 cm. Sections are submitted as follows:

Cassette C1: Anterior cervix and section through anterior lower uterine segment.

Cassette C2: Full-thickness sections through anterior endomyometrium and representative section of right adnexal soft tissue.

Cassette C3: Representative section of posterior cervix.

Cassette C4: Representative sections of posterior lower uterine segment.

Cassette C5: Full-thickness section through posterior endomyometrium.

Part D, labeled "sigmoid attachment," consists of three unoriented, irregular, tan-pink to tan-brown, soft tissue fragments measuring 2.9 x 1.5 x 0.6 cm, 1.3 x 0.8 x 0.6 cm and 0.9 x 0.4 x 0.3 cm. The fragments

Page 3 of 7

are serially sectioned, and all fragments are entirely submitted in cassettes D1-D3.

Part E, labeled "left pelvic lymph node," consists of multiple unoriented, tan-yellow, fibrofatty, soft tissue fragments measuring 4.9 x 3.6 x 1.1 cm in aggregate. Multiple candidate lymph nodes are isolated from the

fatty tissue, the largest measuring 1.0 cm in greatest dimension. These candidate nodes are submitted in cassettes E1-E2.

Part F, labeled "peri-aortic lymph nodes," consists of an unoriented mass of tan-yellow, fibrofatty tissue with attached lymph nodes. The tissue measures 3.5 x 2.5 x 0.9 cm in aggregate. Candidate lymph nodes are submitted in cassette F1.

[page 4 of 7]
[REDACTED]

Part G, labeled "right pelvic lymph nodes," consists of an unoriented, irregular mass of tan-yellow, fibrofatty tissue measuring 5.5 x 4.1 x 1.1 cm. Candidate lymph nodes are isolated, the largest measuring 2.0 cm in greatest dimension. These candidate lymph nodes are submitted in cassettes G1-G3, with the longer lymph node in G3, bisected and submitted in two fragments.

Part H, labeled "right peri-aortic lymph nodes," consists of unoriented, irregular, tan-yellow, fibrofatty, soft tissue fragments measuring 4.0 x 2.1 x 1.1 cm in aggregate. Candidate lymph nodes are isolated and submitted in cassette H1.

Part I, labeled "omentum," consists of a mass of tan-yellow, fibrofatty, soft tissue measuring 80.0 x 12.5 x 3.5 cm. There are scattered areas of hemorrhage, but no distinct lesions are identified. Representative sections are submitted in cassettes I1-I3.

Part J, labeled "appendix," consists of an appendix with attached mesoappendix, measuring 3.5 cm in length and 0.4 cm in average diameter. The serosal surface is tan-gray and unremarkable, without any significant inflammation or lesions. After trimming away the mesoappendix, the appendix is entirely submitted in cassettes J1-J2.

[REDACTED]

[REDACTED]

Other Specimens

[REDACTED]

Specimen(s) Received: A: Right axilla sentinel lymph node #1 (FS), B: Non sentinel lymph node #1, C: Re-excision right breast, D: Re-excision right breast

Final Diagnosis

- A. Sentinel lymph node #1, right axilla, biopsy: No tumor identified in one lymph node (0/1); see comment.
- B. Non-sentinel lymph node #1, biopsy: No tumor identified in one lymph node (0/1).
- C. Right breast, re-excision: Benign breast tissue with biopsy site changes; no residual carcinoma identified.
- D. Right breast, re-excision: Benign breast tissue with biopsy site changes ; no

Page 4 of 7

residual carcinoma identified.

[REDACTED]

[REDACTED]

Final Diagnosis

from [REDACTED]

[page 5 of 7]
[REDACTED]
Breast, Right, Excision.

1. Invasive lobular carcinoma, mixed classic, solid, and pleomorphic types, with associated microcalcifications, tumor present at multiple inked surgical margins; see comment.
2. Lymphovascular invasion identified.

[REDACTED]
[REDACTED]
[REDACTED] 36

Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]
[REDACTED]
Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]
[REDACTED]
Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

Page 5 of 7

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]
[REDACTED]
Specimen(s) Received: Vaginal, Thin Prep Imaged

Final Diagnosis

Vaginal, Thin Prep Imaged

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

[page 6 of 7]
[REDACTED]

SPECIMEN ADEQUACY:
Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Atrophic changes

See Below.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Page 6 of 7

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: A: Diaphragm Washing, B: Peritoneal Washing

Final Diagnosis

A: Diaphragm Washing

BENIGN.

Reactive mesothelial cells.

B: Peritoneal Washing

[page 7 of 7]
[REDACTED]

BENIGN.

[REDACTED]

Source: NCI Genomic Data Commons file 3a4e3dd0-b2f3-4122-82ad-25eabd523f2a (TCGA-09-2050.FB343129-010D-430B-AAE4-F7BEB7122279.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).